Somatic mutation profile of tumor specimen TCGA-A3-A8OW-01A (aliquot TCGA-A3-A8OW-01A-11D-A36X-10) from TCGA case TCGA-A3-A8OW, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 37.1 years (13,546 days).
Specimen TCGA-A3-A8OW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf1cf76-8059-42e9-b94e-03c231fbc6db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A8OW-10A (Blood Derived Normal), aliquot TCGA-A3-A8OW-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c309fc4-48a8-4d68-86e8-6406ebad24cb

The open-access MAF lists 28 somatic variants for this specimen: 26 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 21, Silent 2, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99524671; called by muse, mutect2
- ANKAR | c.521T>A p.L174* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99854431; called by muse, mutect2, varscan2
- ANXA1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs776755767, COSV99973999; called by muse, mutect2, varscan2
- ASXL2 | c.1722A>T p.Q574H | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99711630; called by muse, mutect2, varscan2
- CAMSAP2 | c.3913G>A p.G1305S (on ENST00000236925 / NM_001297707.2; = p.G1294S on NM_203459.3) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as COSV99373724; called by muse, mutect2
- CENPF | c.4675T>C p.Y1559H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as rs764497035, COSV65273484; called by muse, mutect2
- CLIC6 | c.1736C>T p.A579V (on ENST00000360731 / NM_001317009.2; = p.A561V on NM_053277.3) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs371684956, COSV62447218; called by muse, mutect2, varscan2
- FMNL2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs766844297, COSV99980112; called by muse, mutect2
- FZD7 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99637306; called by muse, mutect2
- GGN | c.1829A>C p.N610T | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99287556; called by muse, mutect2
- GIMAP4 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1426437956, COSV99750878; called by muse, mutect2, varscan2
- MUC17 | c.8641G>A p.V2881M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.262); catalogued as COSV100074198; called by muse, mutect2, varscan2
- NRAP | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs752825681, COSV63489506; called by muse, mutect2, varscan2
- OBSCN | c.8771A>G p.N2924S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as rs1269856101, COSV99481527; called by muse, mutect2, varscan2
- POLA1 | c.2797G>C p.D933H | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV100985635, COSV100985798; called by muse, mutect2, varscan2
- RNMT | c.674G>A p.C225Y | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100054737; called by muse, mutect2, varscan2
- RUSF1 | c.509T>C p.I170T | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100512455; called by muse, mutect2, varscan2
- SMAD6 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99994213; called by muse, mutect2
- TPX2 | c.1921A>C p.K641Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV100301891; called by muse, mutect2
- TUBB | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); catalogued as COSV100013411; called by muse, mutect2, varscan2
- USP34 | c.7543G>C p.E2515Q | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV101277113; called by muse, mutect2
- BICRA | c.3263dup p.L1088Ffs*21 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.940_941del p.K314Efs*5 | Frame Shift Del (DEL) | VAF 38/160 reads (24%) | called by mutect2, pindel, varscan2
- IGSF1 | c.3901C>A p.Q1301K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); called by muse, mutect2
- PBRM1 | c.873_874del p.E291Dfs*3 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, varscan2
- SKIL | c.813dup p.C272Mfs*14 | Frame Shift Ins (INS) | VAF 32/146 reads (22%) | called by mutect2, pindel, varscan2
- CXCR6 | c.654G>T p.L218= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV99945922; called by muse, mutect2, varscan2
- KBTBD3 | c.978A>G p.Q326= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs756921366, COSV101595706; called by muse, mutect2, varscan2
